TCGA case TCGA-13-1509 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe402983-70da-44db-b7b1-c32702ddde26

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive; Population group: Ashkenazi Jew.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 64.3 years (23,481 days); Year of diagnosis: 2008; Method of diagnosis: Cytology; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Days to last follow up: 2,438 days (6.7 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 127 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 127 days; Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 65.9 years (24,059 days); Days to diagnosis: 578 days (1.6 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 127 days; Disease response: Tumor Free.
- Day 578 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,438 days (6.7 years); Disease response: With Tumor.
- Karnofsky performance status: 40; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-1509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1.5; Shortest dimension: 0.4.
  Slide TCGA-13-1509-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-13-1509-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-13-1509-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Jewish religion heritage indicator: Ashkenazi; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy.
- Follow-up form 2: Treatment outcome at TCGA followup: Stable Disease; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,438 days; disease-specific survival: no event (censored), 2,438 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 578 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-1509-01A-01D-0472-01): tumor purity 0.78, ploidy 1.76, whole-genome doublings 0.
